Somatic mutation profile of tumor specimen MP2PRT-PASFNN-TBP1-A (aliquot MP2PRT-PASFNN-TBP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASFNN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Precursor cell lymphoblastic leukemia, not phenotyped; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,193 days).
Specimen MP2PRT-PASFNN-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09429891-3fcf-41f3-b620-e81d8e8d0cf8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASFNN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASFNN-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d2634e3-b53d-4c44-a1c1-09f191d692e0

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 9, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MOCS1 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 98/251 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893969, CM981300, COSV57933999; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FREM2 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 201/463 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV54835896; called by muse, mutect2, varscan2
- HSPA12B | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 203/508 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs769008328, COSV54765599; called by muse, mutect2, varscan2
- KLHL41 | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 139/374 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as rs150544399; called by muse, mutect2, varscan2
- LRP2 | c.5272G>T p.G1758* | Nonsense Mutation (SNP) | VAF 39/284 reads (14%) | catalogued as COSV55550274; called by muse, mutect2, varscan2
- LRRC4C | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 131/367 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs779147551, COSV53433854, COSV99539617; called by muse, mutect2, varscan2
- MALRD1 | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 183/346 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs972394336; called by muse, mutect2, varscan2
- PAPPA2 | c.1412G>A p.R471K | Missense Mutation (SNP) | VAF 120/370 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62786586; called by muse, varscan2
- PDZD2 | c.6217G>A p.E2073K | Missense Mutation (SNP) | VAF 160/436 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as rs780686264; called by mutect2, varscan2
- PPL | c.4774G>A p.E1592K | Missense Mutation (SNP) | VAF 162/422 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1448277964, COSV52165703; called by muse, mutect2, varscan2
- RPH3AL | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 201/500 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs374739978; called by muse, mutect2, varscan2
- UVSSA | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 104/314 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as rs764339228; called by muse, mutect2, varscan2
- CRAT | c.941G>A p.S314N | Missense Mutation (SNP) | VAF 140/373 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- DCAF8L1 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 352/404 reads (87%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- DZIP1L | c.1795C>A p.P599T | Missense Mutation (SNP) | VAF 138/372 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PLD1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 103/322 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CACNG4 | c.771C>T p.D257= | Silent (SNP) | VAF 159/399 reads (40%) | catalogued as rs774236249; called by muse, mutect2, varscan2
- COL4A1 | c.15C>T p.L5= | Silent (SNP) | VAF 172/513 reads (34%) | catalogued as rs1361056757; called by muse, mutect2
- GPR26 | c.441C>T p.L147= | Silent (SNP) | VAF 461/891 reads (52%) | catalogued as rs755451481; called by muse, mutect2, varscan2
- IFNA10 | c.219G>A p.K73= | Silent (SNP) | VAF 142/207 reads (69%) | called by muse, mutect2, varscan2
- MAGI2 | c.2199G>A p.E733= | Silent (SNP) | VAF 138/341 reads (40%) | called by muse, mutect2, varscan2
- OR52E4 | c.282C>T p.I94= | Silent (SNP) | VAF 108/317 reads (34%) | catalogued as COSV57625985; called by muse, mutect2, varscan2
- PRLR | c.1785C>T p.F595= | Silent (SNP) | VAF 121/330 reads (37%) | catalogued as COSV51494415; called by muse, mutect2, varscan2
- SLC41A3 | c.75C>T p.P25= | Silent (SNP) | VAF 153/446 reads (34%) | catalogued as COSV59989722; called by muse, mutect2, varscan2
- SOX5 | c.1798C>T p.L600= | Silent (SNP) | VAF 103/303 reads (34%) | catalogued as rs761762364; called by muse, mutect2, varscan2
- STXBP5L | c.2248+6014G>A | Intron (SNP) | VAF 109/262 reads (42%) | called by muse, mutect2, varscan2
